MMRF case MMRF_1080 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0866d285-58e7-4f73-a8b0-9cdba14a0e40

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.6 years (24,337 days); ISS stage: II; Days to last known disease status: 617 days (1.7 years); Days to last follow up: 617 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 144 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 159 days; Days to treatment end: 159 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 65.4 g/L; Immunoglobulin A 0.231 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 3.35 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 288 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 32 g/L; Total Protein 11.6 g/dL; Glucose 5.06 mmol/L.
- Day 74 (ECOG 0): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.278 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.33 µg/mL; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.9 mmol/L.
- Day 173 (ECOG 0): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.67 mmol/L.
- Day 261 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 6.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.5 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.44 mmol/L.
- Day 346 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.47 mg/dL; Immunoglobulin G 9.9 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.23 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 5.89 mmol/L.
- Day 444 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.72 mg/dL; Immunoglobulin G 6.2 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 5.34 mmol/L.
- Day 541 (ECOG 0): Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 5.83 mmol/L.
- Day 617 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.665 mg/dL; Immunoglobulin G 6.37 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 1.73 µg/mL; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.1 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day 1: Weight: 90 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1080_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1080_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
